Somatic mutation profile of tumor specimen TCGA-CG-4449-01A (aliquot TCGA-CG-4449-01A-01D-1158-08) from TCGA case TCGA-CG-4449, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 81.3 years (29,705 days).
Specimen TCGA-CG-4449-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83a3f5cd-c395-4c67-9d12-38a2c0b25df2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4449-10A (Blood Derived Normal), aliquot TCGA-CG-4449-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbc34e3f-e813-40ea-a6ed-2b7836a01d24

The open-access MAF lists 101 somatic variants for this specimen: 78 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 19, Nonsense Mutation 6, Frame Shift Del 5, Splice Region 4, Frame Shift Ins 3, 5'Flank 2, In Frame Del 2, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 54/98 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064794311, CM973401, COSV52661102, COSV52687307, COSV99402633; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A2ML1 | c.642T>C p.Y214= | Splice Region (SNP) | VAF 26/68 reads (38%) | catalogued as COSV55292301; called by muse, mutect2, varscan2
- ADCY4 | c.2945G>A p.R982H | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1222967873, COSV60255183; called by muse, mutect2, varscan2
- APBB1 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.013); catalogued as rs749187223, COSV54977232; called by muse, mutect2, varscan2
- ARTN | c.61-4G>A | Splice Region (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99495519; called by muse, mutect2, varscan2
- ATP8B1 | c.725C>G p.S242* | Nonsense Mutation (SNP) | VAF 5/79 reads (6%) | catalogued as COSV52176766; called by muse, mutect2
- BCL2L13 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs752194881, COSV58226293; called by muse, mutect2, varscan2
- BCL2L13 | c.905C>G p.S302C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58226299; called by muse, mutect2
- BIVM-ERCC5 | c.560C>G p.P187R | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV57280305; called by muse, mutect2, varscan2
- BRCA1 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.685); catalogued as rs769380445, COSV58792428; called by muse, mutect2, varscan2
- BRINP2 | c.1719G>C p.Q573H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs1184817045, COSV64177551, COSV64178140; called by muse, mutect2, varscan2
- CD4 | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 59/302 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as COSV50591880; called by muse, mutect2, varscan2
- CFAP44 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV55612407; called by muse, mutect2, varscan2
- CNTN3 | c.1771G>C p.D591H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as COSV55174457; called by muse, mutect2, varscan2
- DAGLA | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs749507427, COSV57197140; called by muse, mutect2, varscan2
- DNAH1 | c.4265C>T p.T1422M | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as rs745784100, COSV101325747; called by muse, mutect2, varscan2
- DOCK7 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.934); catalogued as rs376620846; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EYS | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1403117224, COSV60988846; called by muse, mutect2, varscan2
- FAM120AOS | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV52906438; called by muse, varscan2
- FETUB | c.863del p.N288Tfs*43 | Frame Shift Del (DEL) | VAF 76/297 reads (26%) | catalogued as rs1238188678; called by mutect2, pindel, varscan2
- FGGY | c.959T>A p.M320K | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58035907; called by muse, mutect2
- FLG2 | c.2014G>A p.V672I | Missense Mutation (SNP) | VAF 137/490 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1261118882, COSV66169470; called by muse, mutect2, varscan2
- GRIK2 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 64/259 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV59743321; called by muse, mutect2, varscan2
- HIVEP3 | c.5494G>T p.D1832Y | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56017022; called by muse, mutect2, varscan2
- HOXC10 | c.920T>G p.L307R | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57726513; called by muse, mutect2, varscan2
- HS3ST3A1 | c.638T>C p.M213T | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs778489314, COSV52376114; called by muse, mutect2, varscan2
- HS3ST3B1 | c.593T>C p.M198T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV62906752; called by muse, mutect2, varscan2
- HSPA12B | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV54767379; called by muse, mutect2, varscan2
- HUWE1 | c.12134G>A p.R4045Q | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV53350108; called by muse, mutect2, varscan2
- ITPR3 | c.5216A>G p.D1739G | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV65410842; called by muse, mutect2
- KHDC1 | c.268C>T p.P90S (on ENST00000370384 / NM_001251874.2; = p.P17S on NM_030568.5) | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.932); catalogued as COSV57615083; called by muse, mutect2, varscan2
- KRT72 | c.524T>C p.I175T | Missense Mutation (SNP) | VAF 112/269 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as rs1417014748, COSV53374751; called by muse, mutect2, varscan2
- MSRB3 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776973896, COSV57589429; called by muse, mutect2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 26/104 reads (25%) | catalogued as rs761471964; called by mutect2, varscan2
- NAA16 | c.2285A>T p.Q762L | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV65128642; called by muse, mutect2, varscan2
- NBEAL1 | c.4133T>A p.I1378N | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as COSV71374558; called by muse, mutect2, varscan2
- NDST2 | c.388A>G p.N130D | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100014109, COSV55215576; called by muse, mutect2, varscan2
- NDST3 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.274); catalogued as rs1344144818, COSV56621106; called by muse, mutect2, varscan2
- NEU4 | c.1396G>A p.A466T (on ENST00000391969 / NM_001167602.3; = p.A478T on NM_080741.4) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs144038379, COSV57990734; called by muse, mutect2, varscan2
- NPAP1 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); catalogued as rs1566755060, COSV61505883, COSV61508057; called by muse, mutect2, varscan2
- NTNG1 | c.47T>A p.V16E | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV53975145; called by muse, mutect2, varscan2
- OSBPL1A | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 41/257 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs758566297, COSV60199436; called by muse, mutect2, varscan2
- PDZD8 | c.2387T>G p.L796W | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.733); catalogued as COSV53691221; called by muse, mutect2, varscan2
- PERP | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV69827579; called by muse, mutect2, varscan2
- PGAP1 | c.2393C>G p.S798* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as COSV61326106, COSV61326924; called by muse, mutect2, varscan2
- PPP2R2D | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | catalogued as COSV70779092; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1604A>G p.Y535C (on ENST00000421990 / NM_001136042.2; = p.Y517C on NM_025267.3) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.502); catalogued as COSV64183413; called by muse, mutect2, varscan2
- PTPRC | c.3121G>T p.E1041* | Nonsense Mutation (SNP) | VAF 36/181 reads (20%) | catalogued as COSV61406753, COSV61413746; called by muse, mutect2, varscan2
- RDH8 | c.501G>A p.Q167= (on ENST00000651512; = p.Q147= on NM_015725.4) | Splice Region (SNP) | VAF 33/71 reads (46%) | catalogued as COSV50675496; called by muse, mutect2, varscan2
- RGL2 | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 11/78 reads (14%) | catalogued as COSV101004803; called by muse, mutect2, varscan2
- RYR2 | c.4793G>A p.R1598K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1056392680, COSV63663260, COSV63678077; called by muse, mutect2, varscan2
- SERBP1 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 78/176 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV63413740; called by muse, mutect2, varscan2
- SLC16A7 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1336676910, COSV53896099; called by muse, mutect2, varscan2
- SLC3A2 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 36/472 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.152); catalogued as rs1140538, COSV58603809; called by muse, mutect2
- SLC45A4 | c.649G>C p.D217H (on ENST00000517878 / NM_001286646.2; = p.D166H on NM_001080431.2) | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50142368; called by muse, mutect2, varscan2
- SLC46A3 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); catalogued as rs201432125, COSV57182316; called by muse, mutect2, varscan2
- SPATA31D1 | c.2513T>G p.F838C | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV61197017; called by muse, mutect2, varscan2
- STXBP3 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV64182462; called by muse, mutect2, varscan2
- TDRD1 | c.1551C>A p.G517= | Splice Region (SNP) | VAF 19/150 reads (13%) | catalogued as COSV52591820; called by muse, mutect2, varscan2
- TLCD4 | c.69C>A p.F23L | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100930747, COSV64632626; called by muse, mutect2, varscan2
- TPPP3 | c.354_355del p.G120Cfs*21 | Frame Shift Del (DEL) | VAF 32/119 reads (27%) | catalogued as rs771633144, COSV99339618; called by mutect2, pindel, varscan2
- USP54 | c.1857C>G p.S619R | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV60443889; called by muse, mutect2, varscan2
- WHRN | c.1499T>C p.I500T | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs1207158164, COSV54331581; called by muse, mutect2, varscan2
- WIZ | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54608608; called by muse, mutect2
- XIRP2 | c.8753G>A p.R2918H (on ENST00000628543; = p.R3093H on NM_152381.6) | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs576110894, COSV54679955; called by muse, mutect2, varscan2
- ZBED2 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.108); catalogued as COSV51917659; called by muse, mutect2
- ZBED9 | c.1445G>C p.R482T | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.025); catalogued as COSV101509065, COSV71729486; called by muse, mutect2, varscan2
- ZFAT | c.1110C>G p.I370M | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV64740215; called by muse, mutect2
- ZFHX4 | c.7921G>A p.E2641K | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1306899927, COSV50510794; called by muse, mutect2, varscan2
- ZNF599 | c.1276A>T p.K426* | Nonsense Mutation (SNP) | VAF 24/354 reads (7%) | catalogued as COSV61396562; called by muse, mutect2
- ZNRF3 | c.1112G>A p.R371H (on ENST00000544604 / NM_001206998.2; = p.R271H on NM_032173.3) | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.935); catalogued as rs780878740, COSV60435383; called by muse, mutect2, varscan2
- ATP10B | c.996dup p.V333Cfs*11 | Frame Shift Ins (INS) | VAF 39/122 reads (32%) | called by mutect2, pindel, varscan2
- BIRC6 | c.4498dup p.S1500Kfs*5 | Frame Shift Ins (INS) | VAF 24/98 reads (24%) | called by mutect2, pindel, varscan2
- COL4A1 | c.1808dup p.G604Wfs*13 | Frame Shift Ins (INS) | VAF 18/125 reads (14%) | called by mutect2, pindel, varscan2
- CTDSPL | c.568del p.A190Pfs*16 (on ENST00000273179 / NM_001008392.2; = p.A179Pfs*16 on NM_005808.3) | Frame Shift Del (DEL) | VAF 54/223 reads (24%) | called by mutect2, pindel, varscan2
- KBTBD7 | c.1619_1622del p.A540Gfs*43 | Frame Shift Del (DEL) | VAF 45/226 reads (20%) | called by mutect2, pindel, varscan2
- PIGR | c.931_933del p.V311del | In Frame Del (DEL) | VAF 24/174 reads (14%) | called by pindel, varscan2
- USP19 | c.2272_2280del p.L758_F760del | In Frame Del (DEL) | VAF 24/120 reads (20%) | called by mutect2, pindel, varscan2
- CACNA1A | c.2259T>C p.S753= | Silent (SNP) | VAF 74/427 reads (17%) | catalogued as COSV64200674; called by muse, mutect2, varscan2
- CPSF1 | c.2748C>T p.G916= | Silent (SNP) | VAF 77/245 reads (31%) | catalogued as rs782350591, COSV58233964; called by muse, mutect2, varscan2
- FAM220A | c.300G>A p.P100= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as rs762157954, COSV57626593; called by muse, mutect2, varscan2
- FAT3 | c.1299G>A p.R433= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs749840160, COSV53125078; called by muse, mutect2, varscan2
- ITPKB | c.2571G>A p.R857= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99684602; called by muse, mutect2
- MAP1LC3C | c.294C>T p.S98= | Silent (SNP) | VAF 59/246 reads (24%) | catalogued as rs200481799, COSV61803985; called by muse, mutect2, varscan2
- MRAP2 | c.327C>T p.N109= | Silent (SNP) | VAF 50/155 reads (32%) | catalogued as rs757494182, COSV57632584, COSV57632722; called by muse, mutect2, varscan2
- NRXN3 | c.1818C>T p.S606= (on ENST00000557594 / NM_001272020.2; = p.S1030= on NM_004796.6) | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs150091542, COSV55328392, COSV55332869; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR10Z1 | c.192C>A p.S64= | Silent (SNP) | VAF 116/437 reads (27%) | catalogued as COSV63524768, COSV63525221; called by muse, mutect2, varscan2
- OR5H14 | c.861C>G p.P287= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV101454048, COSV71194101; called by muse, mutect2, varscan2
- PHLDB2 | c.2340G>A p.Q780= (on ENST00000393925 / NM_001134439.2; = p.Q737= on NM_145753.2) | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV67312508; called by muse, mutect2, varscan2
- PRKD1 | c.1761A>G p.E587= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV100121905, COSV59572931; called by muse, mutect2, varscan2
- PTPRZ1 | c.4584T>C p.S1528= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV66439040; called by muse, mutect2, varscan2
- RGS3 | c.2820G>A p.R940= (on ENST00000350696 / NM_001282923.2; = p.R659= on NM_130795.4) | Silent (SNP) | VAF 34/123 reads (28%) | catalogued as COSV59517433; called by muse, mutect2, varscan2
- TET3 | c.4725G>C p.L1575= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV69643212; called by muse, varscan2
- TRAV19 | c.24G>A p.R8= | Silent (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- USP32 | c.1686C>T p.V562= | Silent (SNP) | VAF 125/520 reads (24%) | catalogued as COSV56270489; called by muse, varscan2
- WDR72 | c.3207G>A p.V1069= | Silent (SNP) | VAF 85/299 reads (28%) | catalogued as COSV64748621; called by muse, mutect2, varscan2
- XIRP2 | c.6033T>G p.T2011= (on ENST00000628543; = p.T2186= on NM_152381.6) | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV54708469; called by muse, mutect2, varscan2
- CD300LD | c.40+26A>G | Intron (SNP) | VAF 24/108 reads (22%) | catalogued as COSV60084036; called by muse, mutect2, varscan2
- GP6 | c.*2C>T | 3'UTR (SNP) | VAF 20/54 reads (37%) | catalogued as rs540637093, COSV59979075; called by muse, mutect2, varscan2
- TMEM132E | chr17:34579064 T>C | 5'Flank (SNP) | VAF 10/102 reads (10%) | catalogued as rs770180508; called by muse, mutect2, varscan2
- ZBTB37 | chr1:173864157 A>G | 5'Flank (SNP) | VAF 28/79 reads (35%) | catalogued as rs1455112902; called by muse, mutect2, varscan2
